Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7922, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7922-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB/Gender:

Location:

Soc. Sec. #:

Physician(s):

Path No.:

Client:

Collected:

Received:

Reported:

Hosp #:

Pre-Operative/Clinical History

Pancreatic mass

Specimen(s) Received

A: PANCREATIC DUCT MARGIN

B: COMMON HEPATIC LYMPH NODE

C: GALLBLADDER

D: WHIPPLE

Gross Description

Specimen A is received fresh from the operating room labeled pancreatic duct margin and consists of a 0.7 cm in diameter x 0.3 cm in length anular tan-pink tissue fragment which is entirely submitted for frozen section analysis and resubmitted in cassette [REDACTED]

Specimen B is received in formalin labeled common hepatic lymph node and consists of an ovoid 1.4 x 0.7 x 0.5 cm tan homogeneous lymph node. The specimen is bisected and entirely submitted in cassette [REDACTED]

Specimen C is received in formalin labeled gallbladder.

Size: 8.5 x 3.5 x 3.0 cm.

Serosa: Smooth, congested, dark green. There is an attached 0.5 cm in length clamped patent cystic duct with an attached 0.9 cm in maximum diameter lymph node attached at the neck.

Contents: Approximately 15 cc of viscid, dark green bile, and no choleliths identified.

Mucosa: Velvety, dark green with no polyps or mass lesions identified.

Wall thickness: 0.2 cm.

Representative sections submitted in cassette (C1).

Specimen D is received in formalin labeled Whipple:

Specimen type/procedure: Pancreatoduodenectomy.

Size and description of components:

Stomach: Not present.

Duodenum: 22.0 cm in length with a circumference ranging from 2.7 at the proximal margin and 4.0 cm at the distal margin of resection. The mucosa shows an umbilicated, strictured 1.0 cm, firm area located 1.0 cm from the proximal margin of resection.

Ampulla: The ampulla is 4.5 cm from the proximal margin and demonstrates individual

[page 2 of 5]
termination of the CBD and pancreatic duct. The common bile duct is diffusely stenotic, as well as the pancreatic duct is obstructed.

Pancreas:

Received is the head and uncinate process that measures 5.5 x 4.0 x 3.0 cm.

The specimen is inked as follows:

Pancreatic margin of resection:	Blue
Uncinate:	Black
CBD:	Orange
Posterior/radial:	Green
Vascular groove:	Yellow.

There are no inherent associated vessels or veins present. Sectioning of the uninvolved pancreatic parenchyma shows the usual lobular parenchyma separated by fibrous septa.

Tumor size:

3.0 x 2.5 x 2.0 cm.

Tumor site:

Pancreatic head.

Tumor focality:

Unifocal.

Tumor configuration:

Ill-defined, solid, pale yellow mass with diffusely cystic areas, the largest measuring 0.3 x 0.3 x 0.2 cm. The tumor abuts the duodenum which is centrally retracted and abuts the common bile duct. The pancreatic duct is obstructed with tumor.

Distance from margins:

Pancreatic neck (blue):	0.7 cm.
Uncinate (black):	Abuts.
Radial/posterior (green):	0.6 cm.
Common bile duct:	0.5 cm.
Ampulla:	2.7 cm.
Proximal bowel margin:	2.0 cm.
Distal (duodenal):	12.0 cm.
Vascular groove (yellow):	0.7 cm.
Small bowel:	Abuts.

Common bile duct:

The CBD measures 4.0 cm in length and measures 0.7 cm in maximum diameter. No stent is identified. The tumor abuts the CBD wall which is diffusely strictured and stenotic (and grossly does not invade the wall).

Pancreatic duct:

The pancreatic duct is obstructed and measures 3.0 cm in length with a diameter of 0.2 cm at the margin of resection. The pancreatic duct is diffusely obstructed by tumor which grossly obliterates the duct.

Other:

There are a few pancreatic lymph nodes identified.

Estimated Extent of Invasion:

Invades adjacent structures, duodenum.

Gross bench photos are taken on specimen D.

Representative sections are submitted as follows:

(D1)	Pancreatic neck margin (blue) en face
(D2)*	Sequential sections to include pancreatic duct and vascular groove
(D3, D4)	Uncinate margin (black), perpendicular, including tumor
(D5, D6)	Radial/posterior margin (inked green), perpendicular to include tumor
(D7)	Common bile duct margin, en face

[page 3 of 5]
- (D8) Ampulla
(D9) Proximal bowel margin, en face
(D10) Distal bowel margin, en face
(D11, D12) Vascular groove (yellow), perpendicular, including tumor
(D13) Duodenum and underlying tumor (closest of area of invasion)
(D14, D15) Full thickness section of duodenum and uncinate margin, including tumor
(D16) Uncinate margin and CBD
(D17, D18) Posterior/radial margin (green) and adjacent duodenum, CBD and attached lymph node
(D19) CBD and surrounding parenchyma (strictured area)
(D20) Uninvolved pancreatic parenchyma
(D21) Uninvolved duodenum
(D22-D24) Single potential lymph node, bisected adjacent the pancreas and CBD
(D25) Single potential lymph node, bisected, periduodenal and adjacent the pancreatic neck
(D26-D27) Intact single potential lymph node
(D28-D30) Single peripancreatic potential lymph nodes near the head.

Intraoperative Consultation

Specimen A, frozen section diagnosis "no tumor identified" is rendered by

Microscopic Description

Summary of Pathologic Findings Pancreas (Exocrine) Cancer

Combination of specimens A, B, C, and D:

Specimen:	Pancreatic duct margin (specimen A), common hepatic lymph node (specimen B), gallbladder (specimen C) and head of pancreas and duodenum (specimen D).		
Procedure:	Pancreaticoduodenectomy (Whipple resection with partial pancreatectomy).		
Tumor site:	Head of pancreas.		
Tumor size:	3.0 x 2.5 x 2.0 cm.		
Histologic type:	Pancreatic duct adenocarcinoma.		
Histologic grade (scale 1-4):	Grade 1.		
Lymphatic/vascular invasion:	Present.		
Perineural invasion:	Present.		
Tumor invasion of:			
Peripancreatic soft tissue:	Present.		
Common bile duct (extrapancreatic):	Not applicable.		
Ampulla of Vater or sphincter of Oddi:	Present.		
Duodenal wall:	Present.		
Adjacent large vessels:	Absent.		
Other adjacent organs or structures:	Not applicable.		
Resection margins:			
Common bile duct margin:	Not involved.		
Distal pancreatic margin:	Not involved.		
Pancreas uncinate margin:	Not involved.		

[page 4 of 5]
HISTOLOGY REPORT

Posterior peripancreatic (radial) soft tissue margin:
Duodenal margin:

Not involved.
Not involved.

Distance of invasive carcinoma from closest margin:

Vascular groove, 1mm.

Regional lymph nodes:

Peripancreatic:

Number examined: 13.

Number involved with tumor: 3.

Common hepatic lymph node:

Number examined: 1.

Number involved with tumor: 0.

Node adjacent to gallbladder:

Number examined: 1.

Number involved with tumor: 0.

Total nodes identified: 15.

Total nodes involved with tumor: 3.

Tumor extends into fat adjacent to one lymph node.

Distant metastases: Cannot assess.

Additional pathologic findings: None.

Clinical history: No therapy given.

Treatment effect: Not applicable.

Pathologic stage (TNM): pT3 pN1 pMX.

Diagnosis

PANCREAS, PANCREATIC DUCT MARGIN, SPECIMEN A:
NO EVIDENCE OF TUMOR.

LYMPH NODE, COMMON HEPATIC NODE, SPECIMEN B:
ONE BENIGN LYMPH NODE.

GALLBLADDER, SPECIMEN C:
CHRONIC CHOLECYSTITIS.
BENIGN LYMPH NODE.

WHIPPLE PROCEDURE, SPECIMEN D:
PANCREATIC DUCT ADENOCARCINOMA, LOW GRADE, pT3.

***Electronically Reviewed and Signed Out By

[page 5 of 5]
HISTOLOGY REPORT

END OF REPORT

Page 5 of 5

Source: NCI Genomic Data Commons file 3be3b7e1-7898-4223-8a30-32a4a24438d5 (TCGA-HZ-7922.ED3AC19F-71D5-4A89-88A0-ADA849F22E7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).